Somatic mutation profile of tumor specimen TCGA-EM-A3FQ-01A (aliquot TCGA-EM-A3FQ-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 19.6 years (7,176 days).
Specimen TCGA-EM-A3FQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9883ed46-3e9f-4a32-a925-29f3a59f139a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FQ-10A (Blood Derived Normal), aliquot TCGA-EM-A3FQ-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88602cd8-f811-4b6c-b66e-0cbe70565aa4

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSCB | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV61218701; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- TMEM132B | c.2637G>A p.P879= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs191297957; called by muse, mutect2, varscan2
